Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A81D, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A81D-01A (Primary Tumor).

Unique Patient Identifier:

Short descriptive translation of the pathology review reported by the

Pathoanatomical review

Date:

Date report:

Material: left adrenal

Grossly, there is a soft solid white gray, redish and yellowish tan tumor with a diameter of 7.5 cm with cystic leasions up to 3.7 cm in diameter. The tumor is surrounded by a thin capsule, reaching to the border of the resected specimen.

Histologically, the tumor was composed of Zellballen with eosinophilic cytoplasm with single hyalinic globules. The nuclei are mostly enlarged with prominent chromatin, sometimes with macronucleoli. The number of mitoses is 2/10 HPF. No atypical mitosis. Very small areas if bleeding and small necroses are visible. No evidence for vessel invasion or capsule destruction.

Immunohistochemically, positive staining for synaptophysin, CD56 and to a lesser extent but still significant also chromogranin. Staining for S100 dispayed single but in total a reduced number of sustentacular cells. Negative staining for AE1/3, EMA and p53. Ki67 is positive to in less than 1%.

Final diagnosis: pheochromocytoma

Translated by:

ICD-O-3
Pheochromocytoma NOS 8700/0
Site @ Adrenal gland NOS C74.9
JWS 10/17/13

Source: NCI Genomic Data Commons file 215b4874-4253-4bdf-9f89-40ed707bc17f (TCGA-WB-A81D.A04DB06F-3946-4FBE-A372-C509749E0FC6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).